Gene-level copy-number profile of tumor specimen TCGA-E5-A4TZ-01A from TCGA case TCGA-E5-A4TZ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 64.5 years (23,566 days).
Specimen TCGA-E5-A4TZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.e707f6fe-0990-4377-8842-ea4a00a1a5ec.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,746 have no estimate.
https://portal.gdc.cancer.gov/files/135e116e-a90b-4c26-a105-31f8a7aec14a

Most common (modal) total copy number across autosomal genes: 7 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 12; copy number 3: 2,507; copy number 4: 5,299; copy number 5: 16,452; copy number 6: 14,464; copy number 7: 18,143.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E5-A4TZ-01A-11D-A31K-01): tumor purity 0.67, ploidy 5.96, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 15, i.e. more than twice the modal value of 7; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
